Gene-level copy-number profile of tumor specimen C3N-03025-01 from CPTAC case C3N-03025, project CPTAC-3 (Brain — Gliomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 78.2 years (28,566 days).
Specimen C3N-03025-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Brain; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 9d7c6670-8c36-4c7f-933e-ff582cd0a9ca.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-03025-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,709 have no estimate.
https://portal.gdc.cancer.gov/files/0bde514d-ca1e-41b1-807d-f21e7b4db191

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 8,272; copy number 2: 47,341; copy number 3: 1,938; copy number 4: 1,175; copy number 5: 19; copy number 6: 75; copy number 9: 6; copy number 15: 44; copy number 20: 12; copy number 31: 3; copy number 32: 4; copy number 33: 19; copy number 44: 2; copy number 46: 4.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 150 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:38,981,549–39,229,588, 6 genes, copy number 9: SOS1, SOS1-IT1, RNU6-198P, HSPE1P13, Y_RNA, CDKL4.
- chr4:52,590,960–57,031,158, 100 genes, copy number 5–15 (within-gene range 2–15) (broad region; genes not listed).
- chr12:57,674,665–59,524,184, 44 genes, copy number 20–46: RPL13AP23, OS9, AC025165.2, AGAP2, AGAP2-AS1, TSPAN31, CDK4, MIR6759, MARCHF9, CYP27B1, METTL1, EEF1AKMT3, AC025165.3, TSFM, AVIL, AC025165.5, RNU6-1083P, AC025165.4, CTDSP2, MIR26A2, AC083805.2, AC083805.1, AC083805.3, ATP23, GIHCG, AC084033.1, RN7SKP65, AC084033.2, LINC02403, AC090643.1, AC090643.2, RPL21P103, AC025578.1, AC020637.1, LINC02388, LRIG3, AC068305.2, RPS6P22, AC068305.1, AC108721.2, AC108721.1, RNU6-279P, RNU6-871P, LINC02448.

Autosomal genes at a single copy (total copy number 1): 5,929. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
